Somatic mutation profile of tumor specimen TCGA-P3-A6T3-01A (aliquot TCGA-P3-A6T3-01A-11D-A34J-08) from TCGA case TCGA-P3-A6T3, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 49.7 years (18,143 days).
Specimen TCGA-P3-A6T3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2a692adf-a3a4-4937-b220-61902e9bae51.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-P3-A6T3-10A (Blood Derived Normal), aliquot TCGA-P3-A6T3-10A-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2e871adf-1869-42a0-a2d5-ef1f6679df9d

The open-access MAF lists 112 somatic variants for this specimen: 85 protein-altering or splice-affecting, 26 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 75, Silent 26, Nonsense Mutation 9, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 13/17 reads (76%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs760640852, CM045607, COSV58683415, COSV58688841; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 41/121 reads (34%) | hotspot (GDC flag); catalogued as rs121913344, CM971506, COSV52662281, COSV52987117, COSV53852813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 36/105 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC1 | c.1380G>A p.L460= | Splice Region (SNP) | VAF 27/136 reads (20%) | catalogued as rs1177711941, COSV100580326; called by muse, mutect2, varscan2
- ABHD12 | c.991G>T p.E331* | Nonsense Mutation (SNP) | VAF 15/88 reads (17%) | catalogued as COSV100194911; called by muse, mutect2, varscan2
- ABHD2 | c.579G>C p.K193N | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.58); catalogued as COSV100756461; called by muse, mutect2, varscan2
- ACO2 | c.1157C>T p.T386I | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53444827; called by muse, mutect2, varscan2
- ADGRF5 | c.3010C>T p.P1004S | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.065); catalogued as COSV51930512, COSV51930891; called by muse, mutect2
- AKR1B15 | c.821C>A p.A274D | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101423408; called by muse, mutect2
- ANGPTL3 | c.583C>T p.Q195* | Nonsense Mutation (SNP) | VAF 12/74 reads (16%) | catalogued as rs573428165, COSV99225944; called by muse, mutect2, varscan2
- ANKLE2 | c.1673C>T p.P558L | Missense Mutation (SNP) | VAF 34/161 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.067); catalogued as rs756582528, COSV100514359; called by muse, mutect2, varscan2
- ANKRD11 | c.241G>T p.E81* | Nonsense Mutation (SNP) | VAF 10/87 reads (11%) | catalogued as COSV56366701, COSV99970574; called by muse, mutect2
- ANKS3 | c.731C>G p.S244C | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100423281; called by muse, mutect2, varscan2
- APCDD1 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 42/231 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.896); catalogued as rs1364886727, COSV100790014; called by muse, mutect2, varscan2
- ARHGEF2 | c.1968G>C p.Q656H (on ENST00000361247 / NM_001162383.2; = p.Q628H on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.054); catalogued as COSV100559948, COSV100561160; called by muse, mutect2, varscan2
- ARL4C | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.738); catalogued as COSV100327063, COSV100327090; called by muse, mutect2, varscan2
- ATAD5 | c.5092G>T p.D1698Y | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100430212; called by muse, mutect2, varscan2
- C6 | c.1760G>T p.R587L | Missense Mutation (SNP) | VAF 19/167 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs207465951, COSV54709744, COSV99667758; called by muse, mutect2, varscan2
- CCDC171 | c.730G>C p.E244Q | Missense Mutation (SNP) | VAF 6/150 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV52656595; called by muse, mutect2
- CDH9 | c.889G>C p.V297L | Missense Mutation (SNP) | VAF 41/278 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0.014); catalogued as COSV99151406, COSV99153292; called by muse, mutect2, varscan2
- CEP63 | c.622C>T p.H208Y | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100133103; called by muse, mutect2, varscan2
- CES5A | c.1318C>G p.Q440E | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV51866448, COSV99308015; called by muse, mutect2, varscan2
- CGNL1 | c.3265G>C p.E1089Q | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.799); catalogued as COSV99849136; called by muse, mutect2, varscan2
- CNTN4 | c.2803G>A p.G935R | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100638905, COSV61869329; called by muse, mutect2, varscan2
- COX15 | c.114G>C p.L38F | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as COSV99187600; called by muse, mutect2, varscan2
- DHX15 | c.118C>T p.R40* | Nonsense Mutation (SNP) | VAF 27/68 reads (40%) | catalogued as rs868164768, COSV100391738; called by muse, mutect2, varscan2
- DIPK1C | c.1063C>T p.R355C | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs758060528, COSV59726169; called by muse, mutect2, varscan2
- DMXL2 | c.6626C>T p.S2209L | Missense Mutation (SNP) | VAF 41/192 reads (21%) | SIFT tolerated (0.82); PolyPhen probably damaging (0.977); catalogued as rs1200664389, COSV51840842; called by muse, mutect2, varscan2
- DNMBP | c.428C>T p.P143L | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs371156348; called by muse, mutect2, varscan2
- EEF1A1 | c.1207G>C p.D403H | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.02); catalogued as COSV100303444; called by muse, mutect2, varscan2
- EEF1G | c.67C>T p.Q23* | Nonsense Mutation (SNP) | VAF 18/131 reads (14%) | catalogued as COSV100240653; called by muse, mutect2, varscan2
- EPS15 | c.913C>G p.P305A | Missense Mutation (SNP) | VAF 76/228 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.022); catalogued as COSV100869604; called by muse, mutect2, varscan2
- FAAH | c.379C>G p.Q127E | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99680283; called by muse, mutect2, varscan2
- FASTK | c.382C>T p.R128W | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); catalogued as COSV52542266; called by muse, mutect2, varscan2
- FOXD4L1 | c.94G>C p.E32Q | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.146); catalogued as rs759359093, COSV99380814; called by muse, mutect2, varscan2
- GCAT | c.887A>G p.N296S | Missense Mutation (SNP) | VAF 33/234 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV50650224; called by muse, mutect2, varscan2
- GGA1 | c.1500C>G p.I500M | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV100289874; called by muse, mutect2, varscan2
- GINS2 | c.190G>C p.E64Q | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV99498089; called by muse, mutect2, varscan2
- GLYR1 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.693); catalogued as COSV100424536; called by muse, mutect2, varscan2
- GMDS | c.923G>A p.R308K | Missense Mutation (SNP) | VAF 12/145 reads (8%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs755554492, COSV101070637; called by muse, mutect2
- GRAMD1C | c.755A>G p.E252G | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.057); catalogued as COSV100823001; called by muse, mutect2, varscan2
- GRM3 | c.837C>G p.D279E | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as COSV100862885, COSV64467042; called by muse, mutect2
- H2BC21 | c.194C>G p.S65C | Missense Mutation (SNP) | VAF 51/261 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV100480170, COSV58613204; called by muse, mutect2, varscan2
- HAL | c.1723C>G p.P575A | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.147); catalogued as COSV54120184, COSV99701653; called by muse, mutect2, varscan2
- ITPKB | c.1992C>G p.F664L | Missense Mutation (SNP) | VAF 37/160 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.051); catalogued as COSV99685166; called by muse, mutect2, varscan2
- KIF21B | c.3656G>C p.R1219T | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.272); catalogued as COSV100145129; called by muse, mutect2, varscan2
- LAMP1 | c.1052C>T p.S351L | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.124); catalogued as COSV100208772; called by muse, mutect2, varscan2
- LPAR1 | c.516G>A p.W172* | Nonsense Mutation (SNP) | VAF 23/96 reads (24%) | catalogued as COSV100731013; called by muse, mutect2, varscan2
- LYST | c.190C>T p.Q64* | Nonsense Mutation (SNP) | VAF 17/65 reads (26%) | catalogued as COSV101090278; called by muse, mutect2, varscan2
- MAP3K15 | c.2275G>C p.E759Q | Missense Mutation (SNP) | VAF 53/196 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.149); catalogued as COSV100135691; called by muse, mutect2, varscan2
- MAP4K5 | c.661C>A p.L221I | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99184830; called by muse, mutect2, varscan2
- MAP6 | c.2062C>A p.P688T | Missense Mutation (SNP) | VAF 28/403 reads (7%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.054); catalogued as COSV100496896; called by muse, mutect2
- MCHR2 | c.284G>C p.R95P | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.049); catalogued as COSV56002006, COSV99912673; called by muse, mutect2, varscan2
- MDN1 | c.10921C>G p.Q3641E | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.112); catalogued as COSV101021816; called by muse, mutect2, varscan2
- MIB2 | c.3130G>A p.A1044T | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.457); catalogued as rs868669938, COSV100599039; called by muse, mutect2
- MOG | c.124C>T p.R42W | Missense Mutation (SNP) | VAF 50/330 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.913); catalogued as rs761804456, COSV100973130; called by muse, mutect2, varscan2
- MTCL1 | c.4018G>A p.E1340K (on ENST00000306329 / NM_001378206.1; = p.E1021K on NM_015210.4) | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100095542; called by muse, mutect2, varscan2
- MTHFR | c.690C>A p.F230L | Missense Mutation (SNP) | VAF 123/405 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100928244; called by muse, mutect2, varscan2
- MYPN | c.2465G>T p.R822L | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.14); catalogued as COSV100590612; called by muse, mutect2, varscan2
- NBEA | c.1610G>A p.S537N | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT tolerated (0.82); PolyPhen probably damaging (0.932); catalogued as COSV100084069, COSV99060778; called by muse, mutect2, varscan2
- NPTN | c.38C>T p.S13L | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs780498543, COSV99766842; called by muse, mutect2, varscan2
- OR52N4 | c.416C>A p.T139N | Missense Mutation (SNP) | VAF 16/167 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.162); catalogued as COSV100421760; called by muse, mutect2
- OR5P3 | c.831C>G p.F277L | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.232); catalogued as COSV100103268; called by muse, mutect2, varscan2
- PALLD | c.3364C>T p.R1122* (on ENST00000505667 / NM_001166108.2; = p.R1105* on NM_016081.4) | Nonsense Mutation (SNP) | VAF 53/280 reads (19%) | catalogued as rs145720372; called by muse, varscan2
- PARP1 | c.821C>T p.S274F | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV100829049; called by muse, mutect2, varscan2
- PCLO | c.6046G>C p.E2016Q | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV100429324, COSV100437649; called by muse, mutect2, varscan2
- PITPNB | c.800C>T p.S267L | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1380758741; called by muse, mutect2, varscan2
- PIWIL3 | c.2042A>G p.Y681C | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100177968; called by muse, mutect2, varscan2
- PLCG2 | c.3247C>A p.P1083T | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100842647, COSV63876169; called by muse, mutect2, varscan2
- RNF213 | c.8759C>T p.S2920L | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as COSV100300420, COSV60407129; called by muse, mutect2, varscan2
- SESN3 | c.1054C>G p.Q352E | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.223); catalogued as COSV99565965; called by muse, mutect2, varscan2
- SIRPG | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 29/196 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.024); catalogued as COSV99403976; called by muse, mutect2, varscan2
- SLC29A1 | c.141G>C p.Q47H | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV57580893; called by muse, varscan2
- SLC30A9 | c.371A>G p.K124R | Missense Mutation (SNP) | VAF 32/184 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.132); catalogued as COSV100048507; called by muse, mutect2, varscan2
- SLC35F3 | c.787G>C p.E263Q (on ENST00000366617 / NM_001300845.1; = p.E332Q on NM_173508.4) | Missense Mutation (SNP) | VAF 43/226 reads (19%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.994); catalogued as COSV100784847, COSV64021096; called by muse, mutect2, varscan2
- SLC9C2 | c.1186G>A p.A396T | Missense Mutation (SNP) | VAF 27/221 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as rs141463661, COSV62945834; called by muse, mutect2, varscan2
- SP140L | c.1303G>C p.E435Q | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs1334464921, COSV99707658; called by muse, mutect2
- SPEM2 | c.247C>G p.Q83E | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.142); catalogued as COSV100081268; called by muse, mutect2, varscan2
- STKLD1 | c.187G>A p.D63N | Missense Mutation (SNP) | VAF 42/182 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100912210; called by muse, mutect2, varscan2
- TDP1 | c.1756C>T p.R586W | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs751645810, COSV100188128; called by muse, mutect2, varscan2
- TDRD1 | c.1615G>A p.D539N | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.033); catalogued as COSV99313802, COSV99315111; called by muse, mutect2, varscan2
- TTN | c.80404G>A p.V26802I (on ENST00000591111; = p.V19378I on NM_003319.4) | Missense Mutation (SNP) | VAF 21/60 reads (35%) | PolyPhen benign (0.006); catalogued as rs762332684, COSV100629358; called by muse, mutect2, varscan2
- WNT5A | c.643C>T p.R215C | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV52838823, COSV99225028; called by muse, mutect2, varscan2
- ZNF789 | c.466C>G p.Q156E | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV58875732; called by muse, mutect2, varscan2
- ZNF804A | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.601); catalogued as rs1474857214, COSV100169596, COSV99043240; called by muse, mutect2, varscan2
- ADAMTS4 | c.585C>T p.N195= | Silent (SNP) | VAF 13/78 reads (17%) | catalogued as rs114749477, COSV63488903; called by muse, mutect2, varscan2
- ANKFN1 | c.1482G>A p.L494= | Silent (SNP) | VAF 30/124 reads (24%) | catalogued as rs760608882, COSV100593889, COSV59457227; called by muse, mutect2, varscan2
- CDH15 | c.2319C>T p.F773= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs768569547, COSV99228874; ClinVar: likely benign; called by muse, mutect2, varscan2
- CRISPLD2 | c.999C>T p.R333= | Silent (SNP) | VAF 73/215 reads (34%) | catalogued as rs376122777; called by muse, mutect2, varscan2
- EEF2 | c.1647C>T p.A549= | Silent (SNP) | VAF 39/99 reads (39%) | catalogued as rs758294276, COSV58581167; called by muse, mutect2, varscan2
- ELAVL1 | c.831C>T p.R277= | Silent (SNP) | VAF 88/195 reads (45%) | catalogued as rs768748811, COSV100688509; called by muse, mutect2, varscan2
- ETV3L | c.282G>A p.L94= | Silent (SNP) | VAF 21/104 reads (20%) | catalogued as rs892681618, COSV101485612; called by muse, mutect2, varscan2
- GTF3C3 | c.2181G>A p.L727= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as COSV99827005; called by muse, mutect2, varscan2
- HIC2 | c.120G>A p.R40= | Silent (SNP) | VAF 42/141 reads (30%) | catalogued as rs376578271; called by muse, mutect2, varscan2
- IFT122 | c.3042G>A p.L1014= (on ENST00000348417 / NM_052989.3; = p.L955= on NM_018262.4) | Silent (SNP) | VAF 15/80 reads (19%) | catalogued as COSV99959835; called by muse, mutect2, varscan2
- MNDA | c.900C>T p.I300= | Silent (SNP) | VAF 51/120 reads (43%) | catalogued as rs779802207, COSV63741386; called by muse, mutect2, varscan2
- MRPS17 | c.84G>C p.V28= | Silent (SNP) | VAF 27/183 reads (15%) | catalogued as COSV99567895; called by muse, mutect2, varscan2
- MTNR1A | c.240G>A p.P80= | Silent (SNP) | VAF 11/69 reads (16%) | catalogued as rs149418383; called by muse, mutect2, varscan2
- NCOA6 | c.5391G>A p.L1797= | Silent (SNP) | VAF 19/128 reads (15%) | catalogued as COSV100750344; called by muse, mutect2, varscan2
- OXT | c.39C>T p.L13= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs752871256, COSV99459202; called by muse, varscan2
- PITPNM3 | c.1698C>A p.P566= | Silent (SNP) | VAF 25/50 reads (50%) | catalogued as COSV99339055; called by muse, mutect2, varscan2
- R3HDM2 | c.1860T>C p.N620= | Silent (SNP) | VAF 20/79 reads (25%) | catalogued as COSV100715573; called by muse, mutect2, varscan2
- RAD51B | c.483C>T p.P161= | Silent (SNP) | VAF 35/277 reads (13%) | called by muse, mutect2, varscan2
- RIPK1 | c.828G>T p.P276= | Silent (SNP) | VAF 28/79 reads (35%) | catalogued as COSV99454896, COSV99454960; called by muse, mutect2, varscan2
- RNF213 | c.9573C>A p.L3191= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV100301468; called by muse, mutect2, varscan2
- SLC8A2 | c.585G>A p.L195= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as COSV52639324; called by muse, mutect2, varscan2
- TARBP1 | c.4524C>T p.L1508= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as COSV99242093; called by muse, mutect2, varscan2
- THAP4 | c.1203C>T p.S401= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs1357980631, COSV101126075; called by muse, mutect2, varscan2
- TLR9 | c.2793C>T p.R931= | Silent (SNP) | VAF 56/110 reads (51%) | catalogued as rs1412158405, COSV100645746; called by muse, mutect2, varscan2
- TTLL2 | c.573C>T p.F191= | Silent (SNP) | VAF 23/118 reads (19%) | catalogued as rs1174762850, COSV53442833, COSV53443027; called by muse, mutect2, varscan2
- UBE2I | c.87A>C p.T29= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as COSV100171411; called by muse, mutect2, varscan2
- EIF4A2 | c.999+95G>C | Intron (SNP) | VAF 47/243 reads (19%) | catalogued as COSV99961374; called by muse, mutect2, varscan2
